Somatic mutation profile of tumor specimen C3L-02109-02 (aliquot CPT0109010010) from CPTAC case C3L-02109, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 79.1 years (28,885 days).
Specimen C3L-02109-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 083594e6-6248-477a-98b8-8ef23f56649f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02109-31 (Blood Derived Normal), aliquot CPT0109040002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a8f31d7-54c4-4958-b4cc-c865e479f850

The open-access MAF lists 46 somatic variants for this specimen: 32 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 10, Intron 3, RNA 1, Frame Shift Ins 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 36/197 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 78/517 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM4 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 45/259 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.325); catalogued as rs370415520; called by muse, mutect2, varscan2
- ANKRD34A | c.1103C>G p.P368R | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.931); catalogued as rs781981808; called by muse, mutect2, varscan2
- DNAH5 | c.8828G>A p.R2943H | Missense Mutation (SNP) | VAF 46/278 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs184758570, COSV54203923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ESPL1 | c.5023C>T p.R1675C | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV57761590; called by muse, mutect2, varscan2
- FRMD4B | c.2960A>G p.Y987C | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.012); catalogued as rs758394679, COSV101273630; called by muse, varscan2
- GSDMA | c.956C>G p.P319R | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV56976684; called by muse, mutect2, varscan2
- H3C11 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 31/238 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.323); catalogued as COSV100137683, COSV58899983; called by muse, mutect2, varscan2
- HEPH | c.362G>T p.R121L (on ENST00000343002; = p.R175L on NM_138737.5) | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs376130905, COSV100294341; called by muse, mutect2, varscan2
- MC3R | c.555C>A p.S185R | Missense Mutation (SNP) | VAF 75/474 reads (16%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV54764929; called by muse, mutect2, varscan2
- PSG4 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs138668740, COSV54937886; called by muse, mutect2
- TTC6 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV101606840; called by muse, mutect2, varscan2
- BLNK | c.14A>G p.N5S | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ERMARD | c.1303C>G p.Q435E | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FGD3 | c.1679C>A p.A560E | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- FMR1 | c.1858A>G p.S620G | Missense Mutation (SNP) | VAF 39/267 reads (15%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GALNTL6 | c.110T>C p.V37A | Missense Mutation (SNP) | VAF 35/270 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GORASP2 | c.1039A>T p.M347L | Missense Mutation (SNP) | VAF 36/281 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR63 | c.794T>C p.I265T | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IL9R | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 45/389 reads (12%) | called by muse, mutect2, varscan2
- MUC16 | c.43274C>T p.T14425I | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- NKAP | c.44del p.S15Wfs*117 | Frame Shift Del (DEL) | VAF 4/50 reads (8%) | called by mutect2, pindel
- NR5A1 | c.518T>C p.V173A | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- NVL | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OSBPL1A | c.2174_2183dup p.E729Wfs*19 (on ENST00000319481 / NM_080597.4; = p.E216Wfs*19 on NM_018030.4) | Frame Shift Ins (INS) | VAF 14/104 reads (13%) | called by mutect2, varscan2
- RGPD4 | c.2148G>T p.R716S | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- STAC2 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENT4A | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNFSF14 | c.499T>C p.Y167H | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TWNK | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 48/372 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WNT2 | c.892T>C p.S298P | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRA3 | c.2913T>C p.N971= | Silent (SNP) | VAF 34/311 reads (11%) | called by muse, mutect2, varscan2
- BBS2 | c.1042C>T p.L348= | Silent (SNP) | VAF 67/448 reads (15%) | catalogued as rs1407743093; called by muse, mutect2, varscan2
- CRYBB3 | c.117C>T p.C39= | Silent (SNP) | VAF 62/583 reads (11%) | catalogued as rs764774270, COSV53194520; called by muse, mutect2
- CTAG2 | c.111G>A p.A37= | Silent (SNP) | VAF 18/197 reads (9%) | catalogued as COSV55996300; called by muse, mutect2, varscan2
- DPF1 | c.738G>A p.A246= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs148078050; called by muse, mutect2
- ENTPD6 | c.1398G>A p.L466= | Silent (SNP) | VAF 16/112 reads (14%) | called by muse, varscan2
- GPR101 | c.93C>A p.G31= | Silent (SNP) | VAF 12/103 reads (12%) | called by muse, mutect2, varscan2
- KL | c.63G>A p.L21= | Silent (SNP) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- RASGEF1C | c.222C>T p.I74= | Silent (SNP) | VAF 39/239 reads (16%) | catalogued as rs1012710199; called by muse, mutect2, varscan2
- TESK2 | c.1662C>G p.A554= | Silent (SNP) | VAF 20/150 reads (13%) | called by muse, mutect2, varscan2
- F10 | c.747+17C>A | Intron (SNP) | VAF 62/252 reads (25%) | called by muse, mutect2, varscan2
- MARCHF8 | c.242+569C>T | Intron (SNP) | VAF 25/224 reads (11%) | catalogued as rs564144489; called by muse, mutect2, varscan2
- MKRN9P | n.690G>A | RNA (SNP) | VAF 27/154 reads (18%) | called by muse, mutect2, varscan2
- ZNF251 | c.277+25C>T | Intron (SNP) | VAF 13/111 reads (12%) | called by muse, mutect2
